Somatic mutation profile of tumor specimen TCGA-2G-AAGA-01A (aliquot TCGA-2G-AAGA-01A-11D-A42Y-10) from TCGA case TCGA-2G-AAGA, project TCGA-TGCT (Testicular Germ Cell Tumors). Sex at birth: male; Vital status: Alive; Primary diagnosis: Embryonal carcinoma, NOS; Tissue or organ of origin: Testis, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 38.5 years (14,053 days).
Specimen TCGA-2G-AAGA-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 227473e0-5ea3-408d-87e4-baa2127f1435.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-2G-AAGA-10A (Blood Derived Normal), aliquot TCGA-2G-AAGA-10A-01D-A433-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c9c0f4d7-9bb1-4dd1-9d69-12c1c6f1dcde

The open-access MAF lists 19 somatic variants for this specimen: 14 protein-altering or splice-affecting, 5 silent.
By variant classification: Missense Mutation 13, Silent 5, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PACRGL | c.170G>C p.R57T | Missense Mutation (SNP) | VAF 32/121 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.529); catalogued as rs774157410; called by muse, mutect2, varscan2
- TRAM1L1 | c.121G>C p.E41Q | Missense Mutation (SNP) | VAF 4/92 reads (4%) | SIFT tolerated (0.46); PolyPhen benign (0.12); catalogued as rs1452197082, COSV60292048; called by muse, mutect2
- ASAP3 | c.1295T>C p.V432A | Missense Mutation (SNP) | VAF 15/114 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.564); called by muse, mutect2, varscan2
- FNTA | c.1135C>T p.Q379* | Nonsense Mutation (SNP) | VAF 55/280 reads (20%) | called by muse, mutect2, varscan2
- LRP8 | c.2158G>T p.A720S | Missense Mutation (SNP) | VAF 12/162 reads (7%) | SIFT tolerated (0.05); PolyPhen benign (0.23); called by muse, mutect2
- LTB4R2 | c.1071G>C p.E357D (on ENST00000528054; = p.E326D on NM_019839.5) | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.628); called by muse, mutect2, varscan2
- PCYT2 | c.243G>C p.Q81H | Missense Mutation (SNP) | VAF 16/110 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.722); called by muse, mutect2, varscan2
- PDIK1L | c.258C>G p.H86Q | Missense Mutation (SNP) | VAF 8/104 reads (8%) | SIFT tolerated (0.05); PolyPhen benign (0.348); called by muse, mutect2
- RIF1 | c.4880C>G p.T1627S | Missense Mutation (SNP) | VAF 23/86 reads (27%) | SIFT tolerated (0.63); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ST3GAL4 | c.85G>T p.D29Y | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.31); called by muse, mutect2
- STK3 | c.797G>T p.R266I | Missense Mutation (SNP) | VAF 36/179 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TUBA1C | c.229G>A p.E77K | Missense Mutation (SNP) | VAF 21/131 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.052); called by muse, mutect2, varscan2
- WDR45 | c.33C>G p.S11R | Missense Mutation (SNP) | VAF 7/94 reads (7%) | SIFT tolerated (0.32); PolyPhen benign (0.097); called by muse, mutect2
- ZFHX4 | c.3677G>C p.S1226T | Missense Mutation (SNP) | VAF 9/101 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0.074); called by muse, mutect2
- LRRC45 | c.1726C>T p.L576= | Silent (SNP) | VAF 7/58 reads (12%) | called by muse, mutect2, varscan2
- ORAI2 | c.591C>T p.A197= | Silent (SNP) | VAF 20/72 reads (28%) | catalogued as COSV62689894; called by muse, mutect2, varscan2
- RGS12 | c.1221C>T p.D407= | Silent (SNP) | VAF 13/54 reads (24%) | catalogued as rs372019148; called by muse, mutect2, varscan2
- SLC13A4 | c.108G>A p.S36= | Silent (SNP) | VAF 73/406 reads (18%) | catalogued as rs370307347; called by muse, mutect2, varscan2
- TNRC6A | c.4734C>T p.N1578= | Silent (SNP) | VAF 15/77 reads (19%) | called by muse, mutect2, varscan2
